Somatic mutation profile of tumor specimen TARGET-30-PASLTC-01A (aliquot TARGET-30-PASLTC-01A-01D) from TARGET case TARGET-30-PASLTC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 2.0 years (740 days).
Specimen TARGET-30-PASLTC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 105f24cf-ec05-4353-9d63-93a7d2603e3e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASLTC-10A (Blood Derived Normal), aliquot TARGET-30-PASLTC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c131caa-b98c-45ad-82f7-d7076eed9b55

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.3007C>G p.R1003G | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100602414, COSV58631020; called by muse, mutect2, varscan2
- LILRB1 | chr19:54630471 ins C | 5'Flank (INS) | VAF 9/72 reads (13%) | catalogued as rs1435222659; called by pindel, varscan2
